Surgical pathology report (de-identified scan), TCGA case TCGA-O2-A5IB, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CALGB, specimen TCGA-O2-A5IB-01A (Primary Tumor).

[page 1 of 4]
p1

UUID:D8784ESD-007E-4768-8D0E-E7A3C0CD21DD

Ordering M.D.:

DATE OF BIRTH:
Age/Sex:

APPROBATE:

DATE RECEIVED:

SURGICAL PATHOLOGY REPORT

SPECIMEN(S) SUBMITTED: A. SUBCARINAL LYMPH NODE FS 1, B. LEVEL 3 NODE FS 2, C. ADDITIONAL LEVEL 3 NODE FS3, D. RIGHT TRACHEABRONCHEAL ANGE FS 4, E. LEVEL 4 FS 5, F. MEDIASTINUM FAT THYMUS, G. RIGHT MIDDLE LOBE FS 6, 7, H. RIGHT LOBAR LYMPH NODE, I. ADDITIONAL BRONCHIAL MARGIN FS 8, J. SUPERIOR SEOMENT RIGHT LOWER LOBE AND BRONCHUS, K. NEW BRONCHIAL MARGIN

DIAGNOSIS:

- A. SUBCARINAL LYMPH NODE, EXCISION
- Anthracotic lymph node, negative for tumor
- B. LEVEL 3 LYMPH NODE, EXCISION
- Anthracotic lymph node, negative for tumor
- C. ADDITIONAL LEVEL 3 LYMPH NODE, EXCISION
- Anthracotic lymph node, negative for tumor
- D. RIGHT TRACHEOBRONCHIAL LYMPH NODE, EXCISION:
- Anthracotic lymph node, negative for tumor
- E. LEVEL 4 LYMPH NODE, EXCISION:
- Anthracotic lymph node, negative for tumor
- F. MEDIASTINAL FAT AND THYMUS EXCISION:
- Parietal pleura infiltrated by poorly differentiated squamous cell carcinoma; lymphatic invasion is present
- Chronic pleuritis with fibrosis is also present
- Mature adipose tissue and atrophic fatty tissue, negative for tumor
- G. RIGHT MIDDLE LOBE OF LUNG, LOBECTOMY
- Lung with a poorly differentiated squamous cell carcinoma
- Maximum tumor diameter: 6.0 cm
- Pleural invasion: Present
- Lymphatic invasion: Present
- Vascular invasion: Present
- Peribronchial lymph nodes: Infiltrated by direct tumor extension
- Bronchial resection margin: Positive
- Staging information: pT3, pN1, pMX
- Non-neoplastic lung parenchyma: post-obstructive endogenous lipoid pneumonia

H. RIGHT LOBAR LYMPH NODE : EXCISION

ICD-0-3

Carcinoma, squamous cell NOS
8070/3

Site @ Lung, middle lobe
C34.2

JEW 4/9/13

PATIENT NOTIFIED OF RESULTS		
DR.	NURSE	DATE

[page 2 of 4]
p2

PATH #:

- Lymph node with metastatic squamous cell carcinoma

I. ADDITIONAL BRONCHIAL MARGIN, EXCISION

- Bronchial wall infiltrated by poorly differentiated squamous cell carcinoma

J. SUPERIOR SEGMENT OF RIGHT LOWER LOBE AND BRONCHUS INTERMEDIUS, EXCISION:

- Bronchial wall with focal infiltration by poorly differentiated squamous cell carcinoma
- Both bronchial resection margins are free of tumor; the tumor is very close to the distal resection margin, which is negative for tumor in the frozen section
- The bronchial mucosa also shows chronic inflammation, focal squamous metaplasia and dysplasia
- Three peribronchial lymph nodes are negative for tumor
- The alveolated lung parenchyma of the superior segment of right lower lobe is negative for tumor

K. NEW BRONCHIAL MARGIN, EXCISION:

- Bronchial wall with mild chronic inflammation, negative for invasive tumor
- The bronchial glands show focal squamous metaplasia and severe dysplasia

HISTORY:**MICROSCOPIC:**

See diagnosis.

SPECIAL STAINS:**IMMUNOSTAINS:****GROSS:****A. SUBCARINAL LYMPH NODE FS 1**

Labeled with the patient's name, labeled "subcarinal lymph node", received fresh in the Operating Room for frozen section consultation and subsequently fixed in formalin is a portion of tan-pink tissue measuring 1.5 x 1.5 x 0.2 cm. The specimen is entirely submitted.

A1. Frozen section #1 - 2

B. LEVEL 3 NODE FS 2

Labeled with the patient's name, labeled "level 3 node", received fresh in the Operating Room for frozen section consultation and subsequently fixed in formalin are a couple portions of soft, pink-tan tissue measuring in aggregate 2.0 x 1.0 x 0.3 cm. The specimen is entirely submitted.

B1. Frozen section #2 - 1

B2. Remainder of the specimen

C. ADDITIONAL LEVEL 3 NODE FS 3

Labeled with the patient's name, labeled "additional level 3 node", received fresh in the Operating Room for frozen section consultation and subsequently fixed in formalin in a cassette is a fragmented lymph node measuring 1.6 x 1.0 x 0.3 cm. The specimen is entirely submitted.

C1. Frozen section #3 - 2

[page 3 of 4]
P3

PATIENT: [REDACTED]

PATH #: [REDACTED]

D. RIGHT TRACHEOBRONCHIAL ANGLE FS 4

Labeled with the patient's name, labeled "right tracheobronchial angle", received fresh in the Operating Room for frozen section consultation and subsequently fixed in formalin in a white cassette is an anthracotic lymph node measuring 1.5 x 1.0 x 0.3 cm. The specimen is entirely submitted.

D1. Frozen section #4 - 1

E. LEVEL 4 FS 5

Labeled with the patient's name, labeled "level 4", received fresh in the Operating Room for frozen consultation and subsequently fixed in formalin in a cassette is a tan-pink fragmented lymph node measuring 1.2 x 0.5 x 0.2 cm. The specimen is entirely submitted.

E1. Frozen section #4 - 2

F. MEDIASTINAL FAT THYMUS

Labeled with the patient's name, labeled "mediastinal fat thymus", and received in formalin is a portion of fatty fibrous tissue measuring 4.0 x 3.5 x 2.0 cm. The specimen is serially sectioned and the cut surface of the specimen consists of tan-yellow, lobulated fatty fibrous tissue. Also received with the specimen are two portions of clotted blood measuring in aggregate 4.5 x 0.8 x 0.5 cm. The specimen is entirely submitted.

F1. 3

F2. 3

F3. 3

F4. 3

F5. Remainder of the blood clot - 3

G. RIGHT MIDDLE LOBE FS 6, 7

Labeled with the patient's name, labeled "right middle lobe", and received fresh in the Operating Room for frozen section consultation and subsequently fixed in formalin is a lobe of lung weighing 100 grams and measuring 4.0 x 10.5 x 5.5 cm. The pleural surface is dark red, smooth and glistening. One area shows an area of adhesions measuring up to 2.0 cm. Also, the specimen is previously sectioned and the sectioned area shows a tan, ill-defined firm mass which measures 6.5 x 4.0 x 2.2 cm. The specimen has multiple staple lines. The staple lines are inked black and subsequently removed. The specimen is serially sectioned. The cut surface of the specimen at the center shows an ill-defined, tan-white, firm mass which measures 6.0 x 4.0 cm and the specimen grossly invades the surgical margin. The remainder of the cut surface of the specimen shows dark red, beefy spongy parenchyma. Representative sections are submitted.

G1. Frozen section #6 - 1

G2. Frozen section #7 - 1

G3-G4. Bronchial margin and possible peribronchial tumor, bisected - 1 each

G5. Tumor and overlying pleura - 1

G6. Tumor and resection margin - 1

G7. Section of the parenchyma and overlying pleural adhesion - 1

G8. Representative sections from uninvolved lung parenchyma - 1

H. RIGHT LOBAR LYMPH NODE

Labeled with the patient's name, labeled "right lobar lymph node", and received in formalin are two portions of tan-pink, focally hemorrhagic, fibrous tissue. The first portion measures 1.5 x 0.6 x 0.6 cm and the larger portion measures 2.5 x 2.0 x 1.5 cm. Both specimens are serially sectioned and the cut surface of the specimen shows tan-pink, homogeneous surfaces. The specimen is entirely submitted.

H1. Smaller portion - 4

H2-H3. Remainder of the larger portion of the specimen - 1,2

I. ADDITIONAL BRONCHIAL MARGIN FS 8

Labeled with the patient's name, labeled "additional bronchial margin", and received fresh in the Operating Room for frozen section consultation and subsequently fixed in formalin is a portion of bronchus with attached lung parenchyma. The specimen measures 1.5 x 0.7 x 0.6 cm. The specimen serially sectioned and the cut surface of the specimen is tan-white with a rim of pink, spongy lung parenchyma. The specimen is entirely submitted.

[page 4 of 4]
P4

PATIENT: [REDACTED]

PATH #: [REDACTED]

- I1. Frozen section #8 - 1
I2. 3

J. SUPERIOR MARGIN RIGHT LOWER LOBE AND BRONCHUS INTERMEDIATE

Labeled with the patient's name, labeled "superior segment and right lower lobe bronchus", and received fresh in the Operating Room for frozen consultation and subsequently fixed in formalin is a 39.2 gram wedge of lung measuring 8.0 x 5.2 x 4.0 cm. The specimen has multiple surgical staple lines and the staple line is inked black and subsequently removed. The pleural surface of the specimen is dark red and smooth. The specimen is serially sectioned and the cut surface of the specimen consists of dark red spongy parenchyma. No tumor or nodule is grossly identified. Representative sections are submitted.

- J1. Frozen section #9A (proximal) - 1
J2. Frozen section #9B (distal) - 1
J3. Sections from the main bronchus - 1
J4-J5. Representative sections from the specimen - 1 each

K. NEW BRONCHIAL MARGIN

Labeled with the patient's name, labeled "new bronchial margin", and received in formalin is a section of bronchus measuring 2.0 x 1.0 x 1.5 cm. The specimen is entirely submitted.

- K1. 2

OPERATIVE CALL**OPERATIVE CONSULT (FROZEN):****FS #1-2:**

- Negative nodes

FS #3-5

- Negative nodes

FS #6-7:

- Non-small cell carcinoma, probably squamous cell carcinoma, margins positive for tumor

FS #8:

- Additional margin positive for tumor

FS #9:

- A = proximal and B = distal margin; negative for tumor
- Squamous metaplasia and dysplasia present

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

Source: NCI Genomic Data Commons file 325e23ae-15c6-46d1-acce-bf75a19e5743 (TCGA-O2-A5IB.D8784E5D-007E-4768-8D0E-E7A3C0CD21DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).